Gene-level copy-number profile of tumor specimen TCGA-78-7535-01A from TCGA case TCGA-78-7535, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 45.4 years (16,571 days).
Specimen TCGA-78-7535-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cf13271f-b2ac-4fbf-b9f9-31e67580dac4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7535-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf8f7a00-1bf6-44d0-b108-866418eb8457

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,185; copy number 2: 31,262; copy number 3: 10,720; copy number 4: 15,529; copy number 5: 393; copy number 6: 703; copy number 7: 25; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7535-01A-11D-2062-01): tumor purity 0.6, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,122 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–61,546,172, 26 genes, copy number 5–7: AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6.
- chr5:61,664,145–61,664,239, 1 gene, copy number 7: RNU6-913P.
- chr7:70,972–63,154,934, 1,085 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:24,704,503–24,775,565, 2 genes, copy number 5: AC023796.1, RN7SL38P.
- chr12:24,830,421–24,836,558, 1 gene, copy number 5: AC023796.2.
- chr20:13,714,322–13,784,886, 1 gene, copy number 8: ESF1.
- chr20:19,756,390–20,056,046, 5 genes, copy number 6: AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:20,094,401–20,095,684, 1 gene, copy number 6: AL035454.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
